Gene-level copy-number profile of tumor specimen TCGA-13-0757-01A from TCGA case TCGA-13-0757, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.2 years (25,999 days).
Specimen TCGA-13-0757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a7bcf22d-826a-4d23-a17f-4d6ad5c14666.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0757-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c56137f3-896a-422b-909b-c0b6a846fa2d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 717; copy number 2: 9,599; copy number 3: 17,668; copy number 4: 15,690; copy number 5: 7,209; copy number 6: 5,343; copy number 7: 1,245; copy number 8: 1,031; copy number 9: 259; copy number 10: 459; copy number 11: 25; copy number 12: 491; copy number 13: 3; copy number 14: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0757-01A-01D-0356-01): tumor purity 0.77, ploidy 4.01, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,579 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,808,016–44,172,719, 277 genes, copy number 10–12 (broad region; genes not listed).
- chr1:47,000,898–47,550,753, 21 genes, copy number 7: CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4.
- chr1:53,506,237–54,413,479, 25 genes, copy number 7 (within-gene range 3–7): GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1.
- chr1:107,571,161–107,965,180, 2 genes, copy number 7 (within-gene range 4–7): VAV3, MIR7852.
- chr2:65,436,711–66,200,373, 1 gene, copy number 7 (within-gene range 6–7): AC007389.1.
- chr2:66,235,377–85,698,852, 357 genes, copy number 7 (broad region; genes not listed).
- chr3:187,668,912–190,716,399, 37 genes, copy number 7: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4.
- chr5:58,198–39,424,868, 611 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr7:70,972–27,410,358, 480 genes, copy number 7–11 (broad region; genes not listed).
- chr8:50,859,530–61,944,180, 165 genes, copy number 7 (broad region; genes not listed).
- chr8:73,008,856–73,982,783, 29 genes, copy number 7 (within-gene range 5–7): TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21.
- chr8:76,265,543–77,014,028, 13 genes, copy number 8: RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr10:44,712–38,783,108, 675 genes, copy number 8–14 (broad region; genes not listed).
- chr12:18,242,961–20,753,386, 32 genes, copy number 7 (within-gene range 6–7): PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1.
- chr12:38,078,529–38,087,392, 2 genes, copy number 8: AK6P2, CLUHP8.
- chr19:12,699,194–15,552,317, 148 genes, copy number 8 (broad region; genes not listed).
- chr19:16,577,642–16,660,115, 1 gene, copy number 8 (within-gene range 3–8): AC008764.4.
- chr19:16,610,374–19,358,754, 148 genes, copy number 8–12 (broad region; genes not listed).
- chr19:20,249,052–22,368,952, 90 genes, copy number 8–12 (broad region; genes not listed).
- chr19:29,665,459–30,228,715, 16 genes, copy number 7–12: PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:34,092,561–34,908,188, 36 genes, copy number 8–13: RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838.
- chr19:35,666,516–36,772,825, 71 genes, copy number 7 (broad region; genes not listed).
- chr19:37,411,155–39,943,680, 131 genes, copy number 8–14 (within-gene range 5–14) (broad region; genes not listed).
- chr19:42,752,686–42,855,691, 1 gene, copy number 9 (within-gene range 4–10): PSG8.
- chr19:42,821,863–44,087,318, 62 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr19:44,329,695–46,392,981, 115 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr20:7,831,798–10,434,222, 33 genes, copy number 7: AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2.

Autosomal genes at a single copy (total copy number 1): 195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
